Somatic mutation profile of tumor specimen TCGA-AA-A01D-01A (aliquot TCGA-AA-A01D-01A-01W-A00E-09) from TCGA case TCGA-AA-A01D, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 47.4 years (17,318 days).
Specimen TCGA-AA-A01D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39446191-0fef-427e-aaa7-099ccaeaa0c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01D-10A (Blood Derived Normal), aliquot TCGA-AA-A01D-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fda8437-29eb-4e75-8350-ce1968797ab0

The open-access MAF lists 148 somatic variants for this specimen: 106 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 37, Nonsense Mutation 9, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, Splice Site 2, 3'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL2A1 | c.3508G>A p.G1170S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912891, CM051418, COSV61533548; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.6853G>A p.G2285R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268762655, COSV55105527; ClinVar: likely pathogenic; called by muse, mutect2
- TERT | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs149566858, CM066607, COSV57235537, COSV99720192; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ABCC11 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 244/269 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs769822967, COSV62321867; called by muse, mutect2, varscan2
- AC006059.2 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.847); catalogued as rs767528181; called by muse, mutect2, varscan2
- AHNAK2 | c.10075C>A p.Q3359K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs769204017, COSV60927860; called by muse, mutect2, varscan2
- AHNAK2 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs137934113; called by muse, mutect2, varscan2
- AMER1 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV57663072; called by muse, mutect2, varscan2
- ATP2C2 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373784599; called by muse, mutect2
- AVPR1B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782061896, COSV65637835; called by muse, mutect2, varscan2
- BCL11A | c.2030C>T p.S677L (on ENST00000335712 / NM_001365609.1; = p.S711L on NM_018014.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV59636000; called by muse, varscan2
- BMERB1 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV55510198; called by muse, varscan2
- BPIFA1 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs765939202, COSV62824970; called by muse, mutect2, varscan2
- C1orf198 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 73/135 reads (54%) | catalogued as COSV64176395; called by muse, mutect2, varscan2
- C2orf16 | c.5294G>T p.S1765I | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV62677881; called by muse, mutect2, varscan2
- C8B | c.1173G>C p.E391D | Missense Mutation (SNP) | VAF 145/414 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs369339023; called by muse, mutect2, varscan2
- CABP4 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57799955; called by muse, mutect2, varscan2
- CACNG3 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs780905732, COSV50064181; called by muse, mutect2, varscan2
- CENPL | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61892857; called by muse, varscan2
- COL4A4 | c.2779G>T p.G927* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV61635832; called by muse, mutect2, varscan2
- DECR1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 143/698 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV55170303; called by muse, mutect2, varscan2
- DST | c.4066G>A p.E1356K (on ENST00000361203 / NM_001374722.1; = p.E1030K on NM_001723.6) | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV55035792; called by muse, mutect2, varscan2
- ENOX1 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV54915004; called by muse, varscan2
- ERCC6L | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 58/340 reads (17%) | catalogued as COSV57822202; called by muse, mutect2, varscan2
- ERN1 | c.2563G>T p.D855Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV70504441; called by muse, mutect2
- FAM104B | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59779216; called by muse, mutect2, varscan2
- FAM131A | c.290G>C p.R97P (on ENST00000310585; = p.R128P on NM_144635.5) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55603748; called by muse, mutect2, varscan2
- FAM13B | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV50372301; called by muse, mutect2, varscan2
- FAM180A | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 91/529 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58528388, COSV58529015; called by muse, mutect2, varscan2
- FAM214A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55922316, COSV55924305; called by muse, mutect2, varscan2
- FAT3 | c.1955G>T p.R652I | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV53163413; called by muse, mutect2
- FAT4 | c.11399T>C p.V3800A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV58704344; called by muse, mutect2, varscan2
- FN1 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60562056; called by muse, mutect2, varscan2
- GUCY1A1 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753636564, COSV56655633; called by muse, mutect2, varscan2
- HEATR1 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.516); catalogued as COSV63982773; called by muse, mutect2, varscan2
- KLHL4 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs146910003, COSV64139944; called by muse, mutect2, varscan2
- MAGEE1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100819341, COSV63910782; called by muse, mutect2, varscan2
- MAPK7 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761235886, COSV55191632; called by muse, mutect2, varscan2
- MID2 | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 68/611 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV53313161; called by muse, mutect2, varscan2
- MTA2 | c.1142G>A p.W381* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV53471665; called by muse, mutect2, varscan2
- MTMR8 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66395942; called by muse, mutect2, varscan2
- OBI1 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 162/491 reads (33%) | catalogued as COSV56147067; called by muse, mutect2, varscan2
- P4HA3 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100526018, COSV59043726; called by muse, mutect2
- PCARE | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV59057466; called by muse, mutect2, varscan2
- PIMREG | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 146/401 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as COSV51471844, COSV99338054; called by muse, mutect2, varscan2
- PRAMEF19 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs754660509, COSV65819448; called by muse, mutect2, varscan2
- PRSS8 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs779230970, COSV54898674; called by muse, mutect2, varscan2
- PSMC3 | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54082554; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2142T>A p.D714E | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as COSV51487490; called by muse, mutect2, varscan2
- RASL11A | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV54081207; called by muse, mutect2, varscan2
- RGS6 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100667208; called by muse, mutect2, varscan2
- ROCK1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as rs778669551, COSV67698918; called by muse, mutect2, varscan2
- RRAGB | c.1093G>C p.D365H (on ENST00000262850 / NM_016656.4; = p.D337H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV53330067, COSV53331513; called by muse, mutect2, varscan2
- RSPO4 | c.269-1G>C p.X90_splice | Splice Site (SNP) | VAF 303/347 reads (87%) | catalogued as CS081980; called by muse, mutect2, varscan2
- SEC24D | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs749811700, COSV54884060; called by muse, mutect2, varscan2
- SLC26A8 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757546070, COSV62887376; called by muse, mutect2
- SLC27A2 | c.872A>C p.K291T | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV51061929; called by muse, mutect2, varscan2
- SLC2A3 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 182/422 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV50006921; called by muse, varscan2
- SLC3A1 | c.381C>A p.Y127* | Nonsense Mutation (SNP) | VAF 116/587 reads (20%) | catalogued as rs763645226, COSV53224532; called by muse, mutect2, varscan2
- SMAD4 | c.1539C>G p.Y513* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | catalogued as COSV61693470; called by muse, mutect2, varscan2
- SOS2 | c.944G>T p.R315I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV53573136, COSV53576178; called by muse, mutect2, varscan2
- SPATA18 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs745462753, COSV54649291; called by muse, mutect2, varscan2
- STMN1 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV63481445; called by muse, mutect2
- TCHH | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | PolyPhen benign (0.044); catalogued as COSV64277316; called by muse, varscan2
- THBS1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs776897123, COSV52953441; called by muse, mutect2
- TMEM164 | c.556G>A p.V186M (on ENST00000372068 / NM_032227.4; = p.V37M on NM_017698.2) | Missense Mutation (SNP) | VAF 218/576 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV55815118; called by muse, mutect2, varscan2
- TMOD1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760447981, COSV52251876; called by muse, mutect2, varscan2
- TTN | c.37069A>G p.K12357E (on ENST00000591111; = p.K4933E on NM_003319.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | PolyPhen probably damaging (0.994); catalogued as COSV60293486; called by muse, mutect2, varscan2
- UBXN4 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 100/367 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51556308; called by muse, mutect2, varscan2
- UGT1A9 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 308/792 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs766064889, COSV60849703; called by muse, varscan2
- UNC5C | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV71661884; called by muse, mutect2, varscan2
- UNC5D | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV54819187; called by muse, mutect2, varscan2
- WDR3 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV62524929; called by muse, mutect2
- WLS | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as COSV52046026; called by muse, mutect2, varscan2
- YIPF6 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs763487554, COSV65856204; called by muse, mutect2, varscan2
- ZC3H8 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV55620641; called by muse, mutect2, varscan2
- ZNF367 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64547627; called by muse, mutect2, varscan2
- ZNF57 | c.1055A>G p.Q352R | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.589); catalogued as rs751297341, COSV60982790; called by muse, varscan2
- BMP7 | c.761-1G>T p.X254_splice | Splice Site (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2
- CAMSAP1 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.439); called by muse, mutect2
- CELSR2 | c.7599G>A p.M2533I | Missense Mutation (SNP) | VAF 184/188 reads (98%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, varscan2
- COL6A3 | c.3237G>T p.E1079D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CUX2 | c.193del p.A65Lfs*4 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- ESCO1 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FICD | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 351/356 reads (99%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.11); called by muse, varscan2
- FLG2 | c.5969T>G p.V1990G | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- GAS2L2 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, varscan2
- H2BC10 | c.102_118del p.K35Vfs*45 | Frame Shift Del (DEL) | VAF 47/154 reads (31%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2
- LRRK2 | c.2383G>T p.A795S | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2
- MED13L | c.6511G>T p.E2171* | Nonsense Mutation (SNP) | VAF 81/129 reads (63%) | called by muse, varscan2
- MSL2 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 266/443 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFKB1 | c.2795C>T p.S932F (on ENST00000394820 / NM_001382627.1; = p.S933F on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NRAP | c.1422del p.D476Mfs*11 (on ENST00000359988 / NM_001322945.2; = p.D441Mfs*11 on NM_006175.4) | Frame Shift Del (DEL) | VAF 104/236 reads (44%) | called by pindel, varscan2
- NRSN1 | c.264dup p.K89Qfs*21 | Frame Shift Ins (INS) | VAF 10/98 reads (10%) | called by mutect2, pindel
- OIT3 | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 321/542 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR6K6 | c.375C>A p.C125* (on ENST00000368144; = p.C101* on NM_001005184.1) | Nonsense Mutation (SNP) | VAF 305/1057 reads (29%) | called by muse, mutect2, varscan2
- PIGO | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PRUNE2 | c.4313G>T p.R1438I | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PWWP3B | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, varscan2
- TJP2 | c.2562dup p.T855Yfs*11 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- VAV1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF568 | c.448del p.E150Kfs*15 | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | called by mutect2, pindel, varscan2
- ZNF586 | c.46A>C p.T16P | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AHNAK2 | c.12396G>A p.K4132= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as COSV100318855; called by muse, mutect2, varscan2
- ANK3 | c.8427G>A p.V2809= | Silent (SNP) | VAF 135/462 reads (29%) | catalogued as COSV55077812; called by muse, mutect2, varscan2
- ANKRD30A | c.2070C>T p.L690= (on ENST00000611781; = p.L634= on NM_052997.2) | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as COSV64618952; called by muse, mutect2, varscan2
- ARHGAP4 | c.792C>T p.D264= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1557104716, COSV63134042; called by mutect2, varscan2
- ATP2B2 | c.3033C>T p.V1011= (on ENST00000352432; = p.V977= on NM_001683.5) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100660469, COSV59506041; called by muse, varscan2
- CD163L1 | c.3204C>T p.S1068= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs774261450, COSV58011939; called by muse, mutect2, varscan2
- COL4A6 | c.4443G>A p.P1481= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs754981173, COSV57875500; called by muse, mutect2, varscan2
- CYRIB | c.459G>A p.Q153= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as COSV67831005, COSV67832617; called by muse, mutect2, varscan2
- DCAF12L1 | c.963C>T p.Y321= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV64422577; called by muse, mutect2, varscan2
- EMC3 | c.744C>T p.F248= | Silent (SNP) | VAF 111/252 reads (44%) | catalogued as rs769523238, COSV55278089; called by muse, varscan2
- FBXL7 | c.840G>A p.T280= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs751663784, COSV61652062; called by muse, mutect2, varscan2
- FRMPD2 | c.825G>A p.A275= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs149962060; called by muse, mutect2, varscan2
- FUT1 | c.588G>A p.Q196= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100038084, COSV59569750; called by muse, mutect2
- GLI1 | c.2274C>T p.P758= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV57366291; called by muse, mutect2, varscan2
- GPR75 | c.705C>T p.V235= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as rs1429380064; called by muse, mutect2
- HPSE2 | c.1149G>A p.V383= | Silent (SNP) | VAF 120/147 reads (82%) | catalogued as COSV65199654; called by muse, mutect2, varscan2
- KCNK2 | c.117G>A p.T39= (on ENST00000444842 / NM_001017425.3; = p.T24= on NM_014217.4) | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV67207072; called by muse, mutect2, varscan2
- KMT2E | c.3319C>T p.L1107= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV57578709; called by muse, mutect2, varscan2
- LRFN2 | c.903G>A p.L301= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- LRIF1 | c.1017C>A p.T339= | Silent (SNP) | VAF 112/1284 reads (9%) | called by muse, mutect2
- NIPAL3 | c.627G>T p.V209= | Silent (SNP) | VAF 16/189 reads (8%) | catalogued as COSV50236521; called by muse, mutect2
- OR52B4 | c.831G>A p.P277= | Silent (SNP) | VAF 92/305 reads (30%) | catalogued as rs201717807, COSV68769412; called by muse, mutect2, varscan2
- PCDHA3 | c.387C>T p.N129= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1554121552, COSV65365560; called by muse, mutect2, varscan2
- PCMTD1 | c.873G>T p.V291= | Silent (SNP) | VAF 54/207 reads (26%) | catalogued as COSV62125126; called by muse, mutect2, varscan2
- PIGO | c.2289G>A p.V763= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs751387350, COSV53055063; called by muse, mutect2, varscan2
- PIGO | c.1983G>A p.V661= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2
- PRELP | c.981C>T p.N327= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1352494079, COSV58117352; called by muse, mutect2, varscan2
- PTPRA | c.1725G>A p.V575= | Silent (SNP) | VAF 250/488 reads (51%) | catalogued as COSV53787371; called by muse, mutect2, varscan2
- RANBP6 | c.969A>C p.L323= | Silent (SNP) | VAF 54/117 reads (46%) | catalogued as COSV52391201; called by muse, mutect2, varscan2
- SCN11A | c.5292C>T p.N1764= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs767633025, COSV56576818; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETD5 | c.1050C>T p.I350= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as COSV56716528; called by muse, mutect2, varscan2
- SHANK1 | c.6186C>T p.S2062= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs547176731, COSV53260372; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A8 | c.243G>A p.V81= | Silent (SNP) | VAF 499/769 reads (65%) | catalogued as COSV57555695; called by muse, mutect2, varscan2
- SNX6 | c.840C>T p.L280= (on ENST00000652385; = p.L152= on NM_021249.5) | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as COSV61920221; called by muse, mutect2
- STAC3 | c.780C>A p.A260= | Silent (SNP) | VAF 55/438 reads (13%) | catalogued as COSV60416028; called by muse, mutect2, varscan2
- XYLB | c.1398C>G p.A466= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV52915443; called by muse, varscan2
- ZNF57 | c.1254G>A p.K418= | Silent (SNP) | VAF 74/210 reads (35%) | catalogued as rs749582167, COSV60984105; called by muse, varscan2
- AL353804.7 | chrX:73846377 G>A | 5'Flank (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- ATP7A | c.-21-8949C>A | Intron (SNP) | VAF 15/64 reads (23%) | catalogued as COSV58453478; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-488C>T | Intron (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5481C>T | 3'UTR (SNP) | VAF 162/544 reads (30%) | catalogued as rs376290394; called by muse, mutect2, varscan2
- SNORD115-30 | n.56A>G | RNA (SNP) | VAF 9/32 reads (28%) | catalogued as rs755965756; called by muse, mutect2, varscan2
